Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5106, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5106-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH FOCAL PAPILLARY (WHO TYPE 1) FEATURES.
- B. FUHRMAN'S NUCLEAR GRADE IS 2 OF 4
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 3.6 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- I. THE ADRENAL GLAND IS UNREMARKABLE.
- J. TNM STAGE: pT1a NX MX.
- K. TNM HISTOLOGIC GRADE = G2.

Source: NCI Genomic Data Commons file 0ddcf876-3ea4-484f-86b2-a6fbc5536faf (TCGA-B0-5106.7F3B2C21-4B5D-4F86-9DB7-AABDEF039A65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).